Somatic mutation profile of tumor specimen C3N-00314-04 (aliquot CPT0012080009) from CPTAC case C3N-00314, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.0 years (28,865 days).
Specimen C3N-00314-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dd86723-c613-4b93-afa7-e7880b0ffe21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00314-31 (Blood Derived Normal), aliquot CPT0012150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e195172-fa08-46a9-9c34-18b1b8e5efd9

The open-access MAF lists 117 somatic variants for this specimen: 79 protein-altering or splice-affecting, 24 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 24, Frame Shift Del 13, Intron 7, Splice Region 4, 3'Flank 3, Nonsense Mutation 3, RNA 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3712G>A p.G1238S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs200733032; called by muse, mutect2, varscan2
- AKAP13 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs779331144, COSV63466066; called by muse, mutect2, varscan2
- AP3B1 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV54877011; called by muse, mutect2, varscan2
- CACNA1C | c.3912+1G>A p.X1304_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | catalogued as rs1247088024; called by muse, mutect2, varscan2
- CSMD3 | c.4069C>G p.P1357A (on ENST00000297405 / NM_001363185.1; = p.P1253A on NM_052900.3) | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52108152; called by muse, mutect2, varscan2
- DNAH5 | c.13084G>T p.D4362Y | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54234974; called by muse, mutect2, varscan2
- EPHA3 | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.926); catalogued as rs760801471, COSV60702159; called by muse, mutect2, varscan2
- LILRA4 | c.96G>C p.W32C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52494279; called by muse, mutect2
- MALRD1 | c.5439G>T p.W1813C | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV65978183; called by muse, mutect2, varscan2
- NLRP12 | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 120/613 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV60752376; called by muse, mutect2, varscan2
- PDCL3 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748802211; called by muse, mutect2, varscan2
- REG3G | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99709302; called by muse, mutect2
- SYNJ2 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745840620; called by muse, mutect2, varscan2
- TRPM6 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs573826879; called by muse, mutect2, varscan2
- USH2A | c.3750G>C p.K1250N | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as COSV100244169, COSV56403783; called by muse, mutect2, varscan2
- ZNF207 | c.780+1G>T p.X260_splice | Splice Site (SNP) | VAF 49/256 reads (19%) | catalogued as COSV58301642; called by muse, mutect2, varscan2
- ZNF419 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1397210318; called by muse, mutect2, varscan2
- ABCA7 | c.4494C>A p.H1498Q | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCC12 | c.3400C>A p.P1134T | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCC5 | c.1832A>G p.Q611R | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACBD5 | c.794A>C p.E265A (on ENST00000375888 / NM_001352568.1; = p.E256A on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2
- ADAMTS14 | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AKAP11 | c.2480A>T p.E827V | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- AKIRIN2 | c.204del p.F69Sfs*17 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.3771dup p.L1258Tfs*4 | Frame Shift Ins (INS) | VAF 30/208 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD42 | c.1058C>G p.T353S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP32 | c.4746_4747del p.R1582Sfs*26 (on ENST00000310343 / NM_001378025.1; = p.R1233Sfs*26 on NM_014715.4) | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | called by pindel, varscan2
- ATP7B | c.3158T>G p.L1053R | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- BMP5 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC178 | c.1883A>C p.K628T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CCDC9 | c.246del p.T83Pfs*85 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- CCNT1 | c.257C>A p.A86E | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CEACAM1 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CHAT | c.1980G>T p.V660= | Splice Region (SNP) | VAF 48/264 reads (18%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.698_700del p.G233del | In Frame Del (DEL) | VAF 33/188 reads (18%) | called by mutect2, pindel, varscan2
- COL6A5 | c.4669G>T p.E1557* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- CRIM1 | c.2788C>T p.H930Y | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX24 | c.739T>C p.F247L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- DEK | c.149del p.K50Rfs*14 | Frame Shift Del (DEL) | VAF 22/129 reads (17%) | called by mutect2, pindel, varscan2
- DNMT1 | c.79C>A p.R27= | Splice Region (SNP) | VAF 35/156 reads (22%) | called by muse, mutect2, varscan2
- DPPA2 | c.329G>C p.S110T | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DUXB | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EPS8 | c.737-8T>A | Splice Region (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- ESPL1 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FOXN1 | c.1573C>G p.L525V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- FSBP | c.152T>G p.V51G | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GASK1B | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GEMIN5 | c.417del p.F139Lfs*11 | Frame Shift Del (DEL) | VAF 19/163 reads (12%) | called by mutect2, pindel, varscan2
- GTF3C5 | c.801T>G p.N267K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HRNR | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 93/465 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGSF10 | c.6162del p.D2055Ifs*4 | Frame Shift Del (DEL) | VAF 39/175 reads (22%) | called by mutect2, pindel, varscan2
- ITGAL | c.3215_3220delinsA p.A1072Dfs*9 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | called by pindel, varscan2*
- ITIH6 | c.3354del p.L1119Cfs*3 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- KCNG1 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KDM5C | c.120del p.K40Nfs*33 | Frame Shift Del (DEL) | VAF 39/98 reads (40%) | called by mutect2, pindel, varscan2
- KLRG2 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARP4B | c.1610del p.L537Yfs*8 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- LIF | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- MECOM | c.1426G>T p.A476S (on ENST00000468789 / NM_001105078.4; = p.A664S on NM_004991.4) | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NUTM1 | c.1600del p.R534Efs*11 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2818del p.L940Sfs*74 (on ENST00000296302 / NM_001366071.2; = p.L940Sfs*68 on NM_018313.5) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel
- PCDHB11 | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNT | c.8040G>T p.E2680D | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIKFYVE | c.5074C>A p.Q1692K | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCO1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SDAD1 | c.196-5T>A | Splice Region (SNP) | VAF 48/212 reads (23%) | called by muse, mutect2, varscan2
- SERPINA12 | c.923T>A p.V308E | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, varscan2
- SETD2 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- SLC4A4 | c.2464G>T p.D822Y (on ENST00000264485 / NM_001098484.3; = p.D778Y on NM_003759.4) | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLTM | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMG1 | c.7465G>A p.D2489N | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SNX25 | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOE1 | c.295T>A p.S99T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TOR3A | c.213del p.W71Cfs*31 | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | called by mutect2, pindel, varscan2
- TSPY1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 150/1236 reads (12%) | called by muse, mutect2, varscan2
- USF3 | c.3549G>T p.E1183D | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZBTB16 | c.1037T>G p.L346W | Missense Mutation (SNP) | VAF 65/367 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZMYM4 | c.4279C>A p.P1427T | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF512B | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC092143.1 | c.1488G>A p.T496= | Silent (SNP) | VAF 61/420 reads (15%) | catalogued as rs371662941; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- AK3 | c.457C>T p.L153= | Silent (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- ARSG | c.411A>G p.K137= | Silent (SNP) | VAF 51/182 reads (28%) | called by muse, mutect2, varscan2
- ATP4A | c.3099C>A p.L1033= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as COSV52872077; called by muse, mutect2, varscan2
- CAPN1 | c.315A>T p.T105= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- DOK2 | c.1116G>T p.A372= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- ESYT3 | c.309C>T p.G103= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- F13A1 | c.867C>A p.P289= | Silent (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- HIP1 | c.309C>G p.L103= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.231T>C p.H77= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs1170472411, COSV51533984; called by muse, mutect2, varscan2
- KCNG1 | c.1182G>C p.L394= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV65369535; called by muse, mutect2, varscan2
- KMT2C | c.8979C>T p.L2993= | Silent (SNP) | VAF 29/242 reads (12%) | catalogued as COSV51439610; called by muse, mutect2, varscan2
- LAMB3 | c.2268G>A p.A756= | Silent (SNP) | VAF 80/424 reads (19%) | catalogued as rs779309922; called by mutect2, varscan2
- MFSD14A | c.852G>A p.A284= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as rs745429649, COSV64514365; called by muse, mutect2, varscan2
- NVL | c.234A>G p.L78= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4473C>T p.I1491= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- PRSS27 | c.444C>T p.P148= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs915952005; called by muse, mutect2, varscan2
- RBMXL3 | c.2553G>C p.R851= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- SERPINB6 | c.1179C>G p.S393= (on ENST00000612421 / NM_001271823.2; = p.S374= on NM_004568.6) | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as rs768602128; called by muse, mutect2, varscan2
- SRRT | c.1062G>C p.R354= | Silent (SNP) | VAF 42/221 reads (19%) | called by muse, mutect2, varscan2
- TMEM151B | c.882C>A p.P294= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- TMEM236 | c.948A>T p.T316= | Silent (SNP) | VAF 100/534 reads (19%) | called by mutect2, varscan2
- ZMYND8 | c.2904G>A p.E968= (on ENST00000311275 / NM_001363741.2; = p.E942= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV53696825; called by muse, mutect2, varscan2
- ZNF516 | c.12C>T p.N4= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as rs754764602; called by muse, mutect2
- AC116366.2 | c.-659_-655del | 5'UTR (DEL) | VAF 25/146 reads (17%) | called by mutect2, pindel, varscan2
- BLOC1S5-TXNDC5 | c.372+39434C>T | Intron (SNP) | VAF 44/237 reads (19%) | called by muse, mutect2, varscan2
- CACNB4 | c.390+55T>G | Intron (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- CRPPA | c.*2284T>G | 3'UTR (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- FAAP20 | chr1:2185418 G>A | 3'Flank (SNP) | VAF 22/335 reads (7%) | catalogued as rs188463485; called by muse, mutect2
- LINC01949 | n.1298C>G | RNA (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- LYPLA2P2 | n.600C>A | RNA (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- NME5 | c.129+27dup | Intron (INS) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- PHF20 | c.1826-137del | Intron (DEL) | VAF 26/141 reads (18%) | called by mutect2, pindel, varscan2
- POMT2 | c.1725+16G>T | Intron (SNP) | VAF 69/298 reads (23%) | called by muse, mutect2, varscan2
- RMDN1 | chr8:86468706 del C | 3'Flank (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel, varscan2
- RN7SL484P | chr15:99792697 G>A | 3'Flank (SNP) | VAF 25/153 reads (16%) | catalogued as rs1407716729; called by muse, mutect2, varscan2
- ZNF528 | c.272-836C>G | Intron (SNP) | VAF 33/189 reads (17%) | catalogued as rs761426106; called by muse, mutect2, varscan2
- ZNF829 | c.-85+146A>C | Intron (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
